Gene-level copy-number profile of tumor specimen TCGA-AA-3675-01A from TCGA case TCGA-AA-3675, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 84.3 years (30,801 days).
Specimen TCGA-AA-3675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.ac7f161c-7081-4f27-8248-591a24ce2b90.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3675-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e05e4237-f06b-4ade-b3e5-2089277b8af6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,379; copy number 2: 53,275; copy number 3: 1,549; copy number 4: 2,435; copy number 5: 181.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3675-01A-02D-0903-01): tumor purity 0.77, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 181 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:162,979,551–164,357,364, 16 genes, copy number 5: AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6.
- chr1:164,639,565–164,680,799, 2 genes, copy number 5: RNU6-171P, AL391001.1.
- chr1:187,706,561–197,775,696, 94 genes, copy number 5 (broad region; genes not listed).
- chr1:236,348,257–241,357,230, 69 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
